Somatic mutation profile of tumor specimen TCGA-66-2789-01A (aliquot TCGA-66-2789-01A-01D-0983-08) from TCGA case TCGA-66-2789, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 73.2 years (26,753 days).
Specimen TCGA-66-2789-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c002954-ee7c-4407-a816-5c309c4e065d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2789-11A (Solid Tissue Normal), aliquot TCGA-66-2789-11A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fec397ae-3435-4451-954e-3949540368a0

The open-access MAF lists 380 somatic variants for this specimen: 278 protein-altering or splice-affecting, 92 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 237, Silent 92, Nonsense Mutation 19, Splice Site 6, Splice Region 5, Frame Shift Del 5, Frame Shift Ins 3, 5'UTR 2, 3'UTR 2, Intron 2, RNA 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.13720C>A p.L4574I | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV68951327; called by muse, mutect2, varscan2
- ABCC12 | c.1516G>C p.G506R | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60912676, COSV60918835; called by muse, mutect2, varscan2
- ABCC9 | c.2955C>A p.Y985* | Nonsense Mutation (SNP) | VAF 16/60 reads (27%) | catalogued as COSV53988437; called by muse, mutect2, varscan2
- ADAM30 | c.1309G>C p.A437P | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65562449; called by muse, mutect2, varscan2
- ADAM33 | c.1589G>C p.W530S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62937159; called by muse, mutect2, varscan2
- ALDH1L1 | c.2161G>C p.D721H | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56420021; called by muse, mutect2, varscan2
- ANGPT4 | c.259G>C p.V87L | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV67923075; called by muse, mutect2, varscan2
- ANGPTL5 | c.660A>G p.L220= | Splice Region (SNP) | VAF 20/51 reads (39%) | catalogued as COSV57534831; called by muse, mutect2, varscan2
- ANK2 | c.1628T>C p.V543A | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.193); catalogued as COSV52192608; called by muse, mutect2, varscan2
- ANKRD30A | c.2960G>C p.G987A (on ENST00000611781; = p.G931A on NM_052997.2) | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV64620926, COSV64623054; called by muse, mutect2, varscan2
- AP3B2 | c.2069C>T p.S690F | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1183087157, COSV55615401; called by muse, varscan2
- AQP1 | c.33G>T p.W11C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV61268362; called by muse, mutect2, varscan2
- ARNT2 | c.871C>A p.P291T | Missense Mutation (SNP) | VAF 93/200 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV57582791, COSV57591217; called by muse, mutect2, varscan2
- ARPP21 | c.450C>A p.H150Q | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs778921161, COSV51809795; called by muse, mutect2, varscan2
- ASPM | c.6671G>C p.W2224S | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV54140161; called by muse, mutect2, varscan2
- ATG2B | c.4315G>A p.E1439K | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as rs773463209, COSV55892334; called by muse, mutect2, varscan2
- ATP10D | c.259G>C p.V87L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56713975; called by muse, mutect2, varscan2
- ATP2C2 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.12); catalogued as rs751429844, COSV52293289; called by muse, mutect2, varscan2
- ATXN7L2 | c.151A>T p.K51* | Nonsense Mutation (SNP) | VAF 22/65 reads (34%) | catalogued as COSV63993025; called by muse, mutect2, varscan2
- AZI2 | c.634C>G p.L212V | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV55425665; called by muse, mutect2, varscan2
- BARHL2 | c.698G>T p.R233L | Missense Mutation (SNP) | VAF 47/185 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV64982182, COSV64982273; called by muse, mutect2, varscan2
- BMP5 | c.1282T>C p.S428P | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1186422804, COSV63707125; called by muse, mutect2, varscan2
- BNC1 | c.2312A>G p.N771S | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1454870812, COSV61759369; called by muse, mutect2, varscan2
- BPNT1 | c.797A>G p.H266R | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs772436104, COSV59041683; called by muse, mutect2, varscan2
- BSND | c.708C>G p.D236E | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.242); catalogued as COSV64870939, COSV64871493; called by muse, mutect2, varscan2
- C10orf120 | c.665A>T p.D222V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV61492820; called by muse, mutect2, varscan2
- C11orf16 | c.1158G>C p.W386C | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58169331; called by muse, mutect2, varscan2
- C1R | c.2041C>T p.R681C (on ENST00000536053 / NM_001354346.2; = p.R667C on NM_001733.7) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs763888790, COSV73383063; called by muse, mutect2, varscan2
- C4orf46 | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.063); catalogued as COSV57016751; called by muse, mutect2, varscan2
- C7 | c.2032A>G p.K678E | Missense Mutation (SNP) | VAF 32/229 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV57482328; called by muse, mutect2, varscan2
- CACNA2D1 | c.1791G>A p.E597= (on ENST00000356253 / NM_001366867.1; = p.E578= on NM_000722.4) | Splice Region (SNP) | VAF 9/42 reads (21%) | catalogued as COSV62394708; called by muse, mutect2, varscan2
- CARD8 | c.724G>C p.E242Q (on ENST00000651546 / NM_001184900.3; = p.E192Q on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.816); catalogued as COSV62875401; called by muse, mutect2, varscan2
- CASP5 | c.961G>T p.G321W | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99507378; called by muse, mutect2, varscan2
- CASR | c.2440C>G p.R814G (on ENST00000490131; = p.R891G on NM_000388.4) | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.614); catalogued as COSV56141963; called by muse, mutect2, varscan2
- CCDC150 | c.325A>T p.S109C | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV55879395; called by muse, mutect2, varscan2
- CCNE1 | c.883C>A p.P295T | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV52906057; called by muse, mutect2, varscan2
- CD33 | c.454A>T p.T152S | Missense Mutation (SNP) | VAF 67/148 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV51805439; called by muse, mutect2, varscan2
- CD55 | c.1021C>A p.H341N | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.146); catalogued as rs771773706, COSV58577039, COSV58578319; called by muse, mutect2, varscan2
- CDC25C | c.1262C>T p.P421L | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.039); catalogued as COSV60401478; called by muse, mutect2, varscan2
- CDH12 | c.275C>A p.T92N | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1294788946, COSV66454248; called by muse, mutect2, varscan2
- CFAP206 | c.1792G>T p.A598S | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV65811032; called by muse, mutect2, varscan2
- CGN | c.2027G>T p.G676V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.025); catalogued as COSV54974280; called by mutect2, varscan2
- CHGB | c.1620C>A p.D540E | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV66761990; called by muse, mutect2, varscan2
- CIAO3 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs766170341, COSV52401831; called by muse, mutect2, varscan2
- CLCA1 | c.1594T>G p.W532G | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.033); catalogued as COSV52332022; called by muse, mutect2, varscan2
- CLDN16 | c.534G>C p.L178F | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV53229550; called by muse, mutect2
- CLDN25 | c.225G>C p.Q75H | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.722); catalogued as COSV71620504; called by muse, mutect2, varscan2
- CLEC4C | c.536G>T p.R179L | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV63582305, COSV63582674; called by muse, mutect2, varscan2
- CLIP2 | c.2590G>T p.E864* | Nonsense Mutation (SNP) | VAF 7/47 reads (15%) | catalogued as COSV56282484, COSV56287235; called by muse, mutect2, varscan2
- CLTC | c.2741C>T p.P914L | Missense Mutation (SNP) | VAF 36/53 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52251618; called by muse, mutect2, varscan2
- CMPK2 | c.949G>T p.E317* | Nonsense Mutation (SNP) | VAF 15/74 reads (20%) | catalogued as COSV56773947, COSV56775557; called by muse, mutect2, varscan2
- CNGA2 | c.1468G>C p.E490Q | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61706529; called by muse, mutect2, varscan2
- CNTN3 | c.1084-2A>T p.X362_splice | Splice Site (SNP) | VAF 11/33 reads (33%) | catalogued as COSV55186308; called by muse, mutect2, varscan2
- CNTN5 | c.780A>T p.Q260H | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54363935; called by muse, mutect2, varscan2
- COL22A1 | c.1715G>C p.G572A | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57359978, COSV57364011; called by muse, mutect2, varscan2
- COL22A1 | c.1714G>T p.G572* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV57364017; called by muse, mutect2, varscan2
- COL4A2 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.971); catalogued as rs748157227, COSV64635328; called by muse, mutect2, varscan2
- COPZ2 | c.430A>G p.K144E | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV50058518; called by muse, mutect2, varscan2
- CORIN | c.1054G>C p.D352H | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1388599712, COSV56691499, COSV56700857; called by muse, mutect2, varscan2
- CPS1 | c.4327A>G p.T1443A | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.566); catalogued as CM063921, COSV51826541; called by muse, mutect2, varscan2
- CSF2RB | c.229C>T p.L77F | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as rs747432440, COSV53261476; called by muse, mutect2, varscan2
- CSMD3 | c.8654G>C p.R2885T (on ENST00000297405 / NM_001363185.1; = p.R2716T on NM_052900.3) | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.996); catalogued as COSV52339922; called by muse, mutect2, varscan2
- CTBP1 | c.1108G>T p.V370L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.063); catalogued as rs7687296; called by mutect2, varscan2
- CTNNA3 | c.2574G>T p.L858F | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65530553; called by muse, mutect2, varscan2
- DAGLA | c.408C>G p.L136= | Splice Region (SNP) | VAF 15/68 reads (22%) | catalogued as COSV57194616, COSV57200656; called by muse, mutect2, varscan2
- DBR1 | c.979G>T p.V327L | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as COSV53431380; called by muse, mutect2, varscan2
- DDHD2 | c.1211A>G p.D404G | Missense Mutation (SNP) | VAF 45/330 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1037978632, COSV68158961; called by muse, mutect2, varscan2
- DHX35 | c.1837G>A p.G613S | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1300513398, COSV52675043; called by muse, mutect2, varscan2
- DIAPH1 | c.283C>G p.L95V | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53889442; called by muse, mutect2, varscan2
- DNAH11 | c.7109C>G p.S2370* | Nonsense Mutation (SNP) | VAF 31/100 reads (31%) | catalogued as COSV60972282, COSV60985668; called by muse, varscan2
- DNAH7 | c.2453C>T p.P818L | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs770136619, COSV56768039; called by muse, mutect2, varscan2
- DNAH9 | c.991G>T p.V331L | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV52380270; called by muse, mutect2, varscan2
- DNMT3B | c.1040G>A p.G347D | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52424556; called by muse, mutect2, varscan2
- DOCK1 | c.3532A>T p.M1178L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54762978; called by muse, mutect2, varscan2
- DOCK8 | c.6299A>T p.*2100Lext*32 | Nonstop Mutation (SNP) | VAF 24/68 reads (35%) | catalogued as COSV66624383; called by muse, mutect2, varscan2
- DRD3 | c.809A>G p.Q270R | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.182); catalogued as rs1559979434, COSV55683245; called by muse, mutect2, varscan2
- DRP2 | c.1509G>C p.L503F | Missense Mutation (SNP) | VAF 62/124 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65812101; called by muse, mutect2, varscan2
- DSCAML1 | c.4559G>A p.S1520N (on ENST00000321322; = p.S1460N on NM_020693.4) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.673); catalogued as rs961343524, COSV58404324; called by muse, mutect2, varscan2
- DSEL | c.177T>A p.D59E | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.034); catalogued as COSV59495376; called by muse, mutect2, varscan2
- DSG1 | c.2185C>A p.P729T | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99935760; called by muse, mutect2, varscan2
- DST | c.21440A>T p.Y7147F (on ENST00000361203 / NM_001374722.1; = p.Y4844F on NM_015548.5) | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55044441; called by muse, mutect2, varscan2
- ELP2 | c.113G>T p.C38F | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV52371733; called by muse, mutect2, varscan2
- ENAM | c.2254G>A p.A752T | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as rs769115693, COSV68535985, COSV68537216; called by muse, mutect2, varscan2
- EPHA5 | c.1961A>G p.H654R | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.229); catalogued as COSV56678482; called by muse, mutect2, varscan2
- EPX | c.1529T>C p.V510A | Missense Mutation (SNP) | VAF 37/53 reads (70%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.847); catalogued as rs550512572, COSV56599699; called by muse, mutect2, varscan2
- ERICH3 | c.3637G>T p.E1213* | Nonsense Mutation (SNP) | VAF 22/66 reads (33%) | catalogued as COSV58620584; called by muse, mutect2, varscan2
- ERICH3 | c.2452C>A p.Q818K | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.033); catalogued as COSV58620594; called by muse, mutect2, varscan2
- ETF1 | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.21); PolyPhen benign (0.092); catalogued as COSV100620791, COSV61930763; called by muse, mutect2, varscan2
- FADS3 | c.868G>T p.V290L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV53880779; called by muse, mutect2, varscan2
- FAM155A | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV65590580; called by muse, mutect2, varscan2
- FCGR2B | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV52683495; called by muse, mutect2, varscan2
- FCRL3 | c.661G>C p.D221H | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.014); catalogued as rs1323496725, COSV63845468; called by muse, mutect2, varscan2
- FMR1 | c.1862T>A p.V621E | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.063); catalogued as COSV54427979; called by muse, mutect2, varscan2
- FRMPD4 | c.2527G>T p.D843Y | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV101042387, COSV66224629; called by muse, mutect2, varscan2
- FSTL5 | c.458T>C p.L153S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750166053, COSV60235229; called by muse, varscan2
- FSTL5 | c.438C>A p.S146R | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV60235241; called by muse, varscan2
- FTSJ3 | c.2257-2A>G p.X753_splice | Splice Site (SNP) | VAF 49/86 reads (57%) | catalogued as COSV63791592; called by muse, mutect2, varscan2
- GABRA6 | c.1156G>T p.E386* | Nonsense Mutation (SNP) | VAF 28/59 reads (47%) | catalogued as rs773585316, COSV50881005, COSV50897415; called by muse, mutect2, varscan2
- GAREM1 | c.1300C>A p.L434I | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV52509657, COSV52516727; called by muse, mutect2, varscan2
- GLCCI1 | c.1274G>C p.R425P | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56205799; called by muse, mutect2, varscan2
- GLT1D1 | c.1014G>T p.R338S (on ENST00000442111 / NM_001366889.1; = p.R258S on NM_144669.3) | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT tolerated (0.8); PolyPhen benign (0.023); catalogued as COSV55889209; called by muse, mutect2, varscan2
- GOLGB1 | c.2819G>C p.R940T | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.299); catalogued as COSV61463091, COSV61472007; called by muse, mutect2, varscan2
- GP2 | c.665G>A p.S222N (on ENST00000381362 / NM_001007240.3; = p.S219N on NM_001502.4) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.068); catalogued as COSV56892832, COSV56897123; called by muse, mutect2
- GPR101 | c.258del p.W87Gfs*57 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | catalogued as rs1339496374; called by mutect2, pindel, varscan2
- GPR20 | c.1007G>A p.G336D | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.207); catalogued as COSV66685182; called by muse, mutect2, varscan2
- GRIN2B | c.50C>A p.A17D | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.146); catalogued as COSV74207776, COSV74208280; called by muse, mutect2, varscan2
- HBS1L | c.1646A>G p.H549R | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs1167868130, COSV63202968; called by muse, mutect2, varscan2
- HCFC2 | c.1505T>G p.L502R | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.727); catalogued as COSV57560679; called by muse, mutect2, varscan2
- HEATR5B | c.4107A>T p.V1369= | Splice Region (SNP) | VAF 32/86 reads (37%) | catalogued as COSV51859843; called by muse, mutect2, varscan2
- HEATR5B | c.3068C>T p.T1023I | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as COSV51859851; called by muse, mutect2, varscan2
- HEPHL1 | c.2372C>A p.T791K | Missense Mutation (SNP) | VAF 61/168 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as COSV59897254; called by muse, mutect2, varscan2
- HEPHL1 | c.2678T>A p.V893E | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV59897267; called by muse, mutect2, varscan2
- HERC2 | c.4297G>T p.V1433L | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.911); catalogued as COSV55326615, COSV55353270; called by muse, mutect2, varscan2
- IGSF6 | c.454C>G p.R152G | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.023); catalogued as COSV51680365; called by muse, mutect2, varscan2
- IL21 | c.118C>A p.R40S | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.061); catalogued as rs1158040184, COSV52647378, COSV52647523; called by muse, mutect2, varscan2
- INTS10 | c.1189G>T p.V397L | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV67605185; called by muse, mutect2
- IQCG | c.246G>T p.M82I | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as COSV54566848; called by muse, mutect2, varscan2
- IRGQ | c.1079G>A p.G360E | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs1484436949, COSV60671664; called by muse, mutect2, varscan2
- ITGA7 | c.1694C>A p.T565N (on ENST00000555728; = p.T521N on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV57702068; called by muse, mutect2, varscan2
- ITGAM | c.1588G>T p.D530Y (on ENST00000648685 / NM_001145808.2; = p.D529Y on NM_000632.4) | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54943548; called by muse, mutect2, varscan2
- ITPRIPL1 | c.284C>T p.P95L (on ENST00000439118 / NM_001008949.3; = p.P103L on NM_178495.6) | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs767020756, COSV63154204; called by muse, mutect2, varscan2
- KIF19 | c.2268C>A p.D756E | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63430769; called by muse, mutect2, varscan2
- KIF19 | c.2269A>G p.S757G | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious (0.05); PolyPhen benign (0.057); catalogued as COSV63430772; called by muse, mutect2, varscan2
- KIF1A | c.5090G>A p.R1697Q (on ENST00000320389 / NM_001379639.1; = p.R1689Q on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.723); catalogued as rs1349426679, COSV57503699; called by muse, mutect2, varscan2
- KLHDC10 | c.858A>T p.L286F | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.156); catalogued as COSV59054344; called by muse, mutect2, varscan2
- KRT5 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV52863877; called by muse, mutect2, varscan2
- KRTAP13-3 | c.420G>C p.Q140H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV61880540, COSV61880552; called by muse, mutect2, varscan2
- LDHB | c.757A>G p.I253V | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.107); catalogued as rs373042868; called by muse, mutect2, varscan2
- LOXL4 | c.2167G>A p.G723R | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53259688; called by muse, mutect2, varscan2
- LRP1B | c.9037G>T p.E3013* | Nonsense Mutation (SNP) | VAF 18/73 reads (25%) | catalogued as COSV67281245, COSV67284862; called by muse, mutect2, varscan2
- LRP6 | c.470G>T p.W157L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99742866; called by muse, varscan2
- LRRC18 | c.728C>G p.P243R | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53286247; called by muse, mutect2, varscan2
- LVRN | c.1529C>A p.A510D | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as COSV63495889, COSV63498628; called by muse, mutect2, varscan2
- LYN | c.766G>C p.G256R | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV70206520; called by muse, mutect2, varscan2
- MBD5 | c.1340G>A p.G447E | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs1282700766, COSV68699166; called by muse, mutect2, varscan2
- MCOLN3 | c.1142C>A p.T381N | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV62016579; called by muse, mutect2, varscan2
- MED12L | c.640G>T p.D214Y | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV56400122, COSV99852246; called by muse, mutect2, varscan2
- MED13L | c.1980G>T p.M660I | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV56131810; called by mutect2, varscan2
- MED14 | c.2786G>A p.R929Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1163992897, COSV61358844; called by muse, mutect2, varscan2
- MED27 | c.201C>G p.L67= | Splice Region (SNP) | VAF 14/48 reads (29%) | catalogued as COSV52607206; called by muse, mutect2, varscan2
- MEF2D | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV61730613; called by muse, mutect2, varscan2
- MEP1B | c.1577C>A p.T526N | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV52500436; called by muse, mutect2, varscan2
- MMP16 | c.804C>A p.Y268* | Nonsense Mutation (SNP) | VAF 41/96 reads (43%) | catalogued as COSV54192617; called by muse, mutect2, varscan2
- MMP17 | c.1067G>T p.R356L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759602929, COSV62181642; called by muse, mutect2, varscan2
- MRPS24 | c.434A>G p.Y145C | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as rs377480969; called by muse, mutect2, varscan2
- MSTN | c.168T>G p.I56M | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53622452; called by muse, varscan2
- MTO1 | c.1612G>A p.E538K (on ENST00000370300 / NM_133645.3; = p.E513K on NM_012123.4) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV100940381; called by muse, mutect2, varscan2
- MYCBP2 | c.9799G>C p.E3267Q (on ENST00000357337; = p.E3305Q on NM_015057.5) | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV62042022; called by muse, mutect2, varscan2
- N4BP2 | c.3751C>T p.P1251S | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.018); catalogued as COSV54704688; called by muse, mutect2, varscan2
- NAXE | c.626G>C p.G209A | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV58041742; called by muse, mutect2, varscan2
- NEBL | c.305C>G p.T102R | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as COSV65844763; called by muse, mutect2, varscan2
- NOTCH1 | c.1285T>A p.C429S | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM149811, COSV53100434; called by muse, mutect2, varscan2
- NOTCH1 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1300110216, COSV53032942; called by muse, mutect2, varscan2
- NRP1 | c.815-1G>T p.X272_splice | Splice Site (SNP) | VAF 14/41 reads (34%) | catalogued as COSV55178965; called by muse, mutect2, varscan2
- NSD3 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 65/443 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV57622406; called by muse, mutect2, varscan2
- NSUN2 | c.722A>G p.H241R | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1321570157, COSV52952645; called by muse, mutect2, varscan2
- OR14A16 | c.362A>G p.Y121C | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as rs376641242, COSV62926942; called by muse, mutect2, varscan2
- OR14C36 | c.769T>C p.Y257H | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.766); catalogued as COSV58603042; called by muse, varscan2
- OR14C36 | c.872G>A p.R291K | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV58603053; called by muse, varscan2
- OR14I1 | c.541C>T p.H181Y | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1040170550, COSV61199525; called by muse, mutect2, varscan2
- OR1S1 | c.282G>C p.M94I | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV58708970; called by muse, mutect2, varscan2
- OR2AK2 | c.224C>A p.S75Y | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV63562544; called by muse, mutect2, varscan2
- OR4F6 | c.655A>G p.I219V | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.02); catalogued as COSV61027736; called by muse, mutect2, varscan2
- OR4N2 | c.610G>T p.G204C | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60052832, COSV60055538; called by muse, mutect2, varscan2
- OR4N2 | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60055551; called by muse, mutect2, varscan2
- OR51A4 | c.370A>G p.R124G | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs768530291, COSV66750161; called by muse, mutect2, varscan2
- OR52L1 | c.560G>T p.C187F | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV59989640; called by muse, mutect2, varscan2
- OR5B21 | c.617T>A p.F206Y | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV64482329; called by muse, mutect2
- OR5J2 | c.420G>T p.K140N | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV100399078, COSV56623613; called by muse, mutect2, varscan2
- OR6F1 | c.73C>A p.L25I | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57469697; called by muse, mutect2
- OR6X1 | c.417C>A p.C139* | Nonsense Mutation (SNP) | VAF 21/108 reads (19%) | catalogued as COSV60009925; called by muse, mutect2, varscan2
- OR9Q2 | c.655C>G p.L219V | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.068); catalogued as COSV61112903; called by muse, mutect2, varscan2
- PAPPA2 | c.2546C>T p.P849L | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.885); catalogued as COSV62788030; called by muse, mutect2, varscan2
- PCDH11X | c.1261G>T p.A421S | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (1); PolyPhen possibly damaging (0.557); catalogued as COSV100015633, COSV53510739; called by muse, mutect2, varscan2
- PDCL3 | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 22/85 reads (26%) | catalogued as COSV51810490; called by muse, mutect2, varscan2
- PDE4DIP | c.4891C>G p.H1631D | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.161); catalogued as COSV57732989; called by muse, mutect2, varscan2
- PDZD7 | c.420C>A p.S140R | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV64647834; called by muse, mutect2, varscan2
- PDZRN3 | c.2316G>T p.E772D | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.039); catalogued as COSV55217439; called by mutect2, varscan2
- PHACTR3 | c.253A>G p.N85D | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1404239146, COSV63035230; called by muse, mutect2, varscan2
- PIGK | c.931G>C p.E311Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.094); catalogued as COSV63063848; called by muse, mutect2, varscan2
- PKHD1L1 | c.9035C>A p.P3012H | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV101005417, COSV65755136; called by muse, mutect2, varscan2
- PLCB4 | c.1138T>A p.C380S | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53820773; called by muse, mutect2, varscan2
- PLGRKT | c.25A>G p.M9V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.484); catalogued as rs1442284578, COSV56352882; called by muse, mutect2, varscan2
- PLXNA1 | c.5045G>T p.R1682L | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52528783, COSV99302684; called by muse, mutect2, varscan2
- PNLIPRP1 | c.418G>A p.V140M | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs781794487, COSV62613802; called by muse, mutect2, varscan2
- POMGNT1 | c.807C>A p.C269* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as CD109741, COSV64341196; called by muse, mutect2, varscan2
- POSTN | c.2098C>A p.L700I | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65712859, COSV65714955; called by muse, mutect2, varscan2
- POU4F1 | c.1149G>T p.E383D | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV65885175; called by muse, mutect2, varscan2
- POU6F1 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV61326467; called by muse, mutect2, varscan2
- PPP2R5B | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.57); catalogued as rs1251706894, COSV51214083; called by muse, mutect2, varscan2
- PRDM16 | c.2861G>A p.R954K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.083); catalogued as COSV54611660; called by muse, mutect2, varscan2
- PSPC1 | c.449G>T p.R150L | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as COSV58891391; called by muse, mutect2, varscan2
- PTPN14 | c.711G>C p.M237I | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as COSV100873044, COSV65289321; called by muse, mutect2, varscan2
- RAB11FIP2 | c.155C>G p.A52G | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as COSV62926306; called by muse, varscan2
- RALGAPA2 | c.5002G>T p.E1668* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV52513242; called by muse, mutect2
- RAPGEF2 | c.941A>G p.K314R | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as COSV52434440; called by muse, mutect2, varscan2
- REG1B | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59308247; called by muse, mutect2, varscan2
- REG1B | c.434-1G>T p.X145_splice | Splice Site (SNP) | VAF 24/46 reads (52%) | catalogued as COSV100521322, COSV59305489; called by muse, mutect2, varscan2
- RGR | c.236+2T>C p.X79_splice | Splice Site (SNP) | VAF 13/52 reads (25%) | catalogued as COSV63895365; called by muse, mutect2, varscan2
- RNASEH1 | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59439883; called by muse, mutect2, varscan2
- RNF40 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV61216932; called by muse, mutect2, varscan2
- RPS8 | c.146G>T p.R49L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV63234453, COSV63234625; called by muse, mutect2, varscan2
- RTN1 | c.2072G>T p.R691M | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV50753803; called by muse, mutect2, varscan2
- RWDD2A | c.433T>C p.S145P | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV52286275; called by muse, mutect2, varscan2
- RXFP3 | c.65C>G p.A22G | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV57508534; called by muse, mutect2
- SASH1 | c.3020C>T p.P1007L | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV66566675; called by muse, mutect2, varscan2
- SDHA | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.909); catalogued as COSV53774383; called by muse, mutect2, varscan2
- SIGLECL1 | c.317T>C p.L106S | Missense Mutation (SNP) | VAF 53/299 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as COSV57065028; called by muse, mutect2, varscan2
- SIRPB1 | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 21/84 reads (25%) | catalogued as COSV53541245; called by muse, mutect2, varscan2
- SIRT7 | c.803G>T p.G268V | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58712837; called by muse, mutect2, varscan2
- SLC24A5 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.15); catalogued as rs1567226824, COSV51048311; called by muse, mutect2, varscan2
- SLC25A33 | c.157C>G p.Q53E | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.97); PolyPhen benign (0.017); catalogued as COSV57019004, COSV57022114; called by muse, mutect2, varscan2
- SLC32A1 | c.783G>T p.K261N | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); catalogued as COSV54148589; called by muse, mutect2, varscan2
- SLC35F3 | c.178G>C p.V60L | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.989); catalogued as COSV64031483, COSV64033414; called by muse, mutect2, varscan2
- SLC38A1 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1190228528, COSV67065101; called by muse, mutect2, varscan2
- SLC6A13 | c.1750G>T p.A584S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV58261032; called by muse, mutect2, varscan2
- SLC6A6 | c.463A>G p.K155E | Missense Mutation (SNP) | VAF 63/218 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV62653314; called by muse, mutect2, varscan2
- SLC9A3 | c.1189C>A p.R397S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53805950; called by muse, mutect2, varscan2
- SLCO1C1 | c.380C>G p.A127G | Missense Mutation (SNP) | VAF 67/248 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.167); catalogued as rs1324185314, COSV56881265; called by muse, mutect2, varscan2
- SLIT2 | c.3905C>A p.T1302N | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.189); catalogued as COSV56598394; called by muse, mutect2, varscan2
- SNAP23 | c.142C>A p.Q48K | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51042395; called by muse, mutect2, varscan2
- SNRPA1 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 59/270 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV54258728; called by muse, mutect2, varscan2
- SORCS1 | c.3406A>G p.T1136A | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV53874510; called by muse, mutect2, varscan2
- SOX8 | c.766C>A p.R256S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.277); catalogued as COSV53510881; called by muse, mutect2, varscan2
- SPART | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as rs960181712, COSV62088966; called by muse, mutect2, varscan2
- STAR | c.40T>G p.Y14D | Missense Mutation (SNP) | VAF 20/496 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV52418649; called by muse, mutect2
- STK31 | c.726G>T p.L242F | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.296); catalogued as COSV63459938; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2764C>T p.L922F | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs746746459, COSV100561634, COSV59139396; called by muse, mutect2, varscan2
- TAAR6 | c.497C>A p.A166D | Missense Mutation (SNP) | VAF 71/203 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.195); catalogued as COSV51584614, COSV51585065; called by muse, mutect2, varscan2
- TAF3 | c.2372G>A p.R791K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.138); catalogued as rs753039563, COSV60212555; called by muse, mutect2, varscan2
- TAF9 | c.233G>T p.R78L | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.597); catalogued as COSV54205482; called by muse, mutect2, varscan2
- TANK | c.13A>G p.I5V | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV52048412; called by muse, mutect2, varscan2
- TAOK1 | c.805C>G p.R269G | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55599767; called by muse, mutect2, varscan2
- TARS3 | c.490G>T p.V164L | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as COSV60108164, COSV60109869; called by muse, mutect2, varscan2
- TENT4A | c.2347C>G p.R783G | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50102759, COSV50103116; called by muse, mutect2, varscan2
- TEX2 | c.968C>G p.S323* | Nonsense Mutation (SNP) | VAF 12/65 reads (18%) | catalogued as COSV51986060; called by muse, mutect2, varscan2
- TMPRSS5 | c.99G>T p.Q33H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.28); catalogued as COSV55426638; called by muse, mutect2, varscan2
- TOGARAM1 | c.2302C>G p.Q768E | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs781383925, COSV63895616; called by muse, mutect2, varscan2
- TOMM40 | c.478C>G p.L160V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as COSV52980515; called by muse, mutect2, varscan2
- TRIM22 | c.736G>C p.V246L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV66091992; called by muse, mutect2
- TRPM2 | c.1835C>G p.S612* | Nonsense Mutation (SNP) | VAF 29/131 reads (22%) | catalogued as rs749681512, COSV55978236; called by muse, mutect2, varscan2
- TSPOAP1 | c.2977C>T p.P993S | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as COSV52119240; called by muse, mutect2, varscan2
- TTN | c.30790G>T p.E10264* (on ENST00000591111; = p.E9337* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV60070172, COSV60391857; called by muse, varscan2
- UBXN10 | c.215A>G p.Y72C | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV66772730; called by muse, mutect2, varscan2
- UGT2A3 | c.625G>C p.V209L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.083); catalogued as COSV52362400; called by muse, mutect2, varscan2
- UGT3A1 | c.1396G>T p.G466W | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761693364, COSV99954245; called by muse, mutect2, varscan2
- UGT3A1 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV57104203; called by muse, mutect2, varscan2
- UGT3A2 | c.1523G>A p.G508D | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV56930131, COSV56933946; called by muse, mutect2, varscan2
- USP5 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.576); catalogued as COSV57532400; called by mutect2, varscan2
- VANGL2 | c.1440A>C p.L480F | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100925620, COSV63605598; called by muse, mutect2, varscan2
- VGLL1 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 41/64 reads (64%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs768578233, COSV65702865; called by muse, mutect2, varscan2
- VN1R4 | c.881G>T p.R294M | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.124); catalogued as COSV60805075, COSV60805180; called by muse, mutect2, varscan2
- VPS51 | c.2279C>T p.A760V | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as COSV54209693; called by muse, mutect2, varscan2
- VWF | c.8155+1G>T p.X2719_splice | Splice Site (SNP) | VAF 13/44 reads (30%) | catalogued as CS125366, COSV54636748; called by muse, mutect2, varscan2
- WDR93 | c.618C>A p.D206E | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs754694160, COSV51535897; called by muse, mutect2, varscan2
- YEATS2 | c.881A>T p.K294M | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV59373225; called by muse, mutect2, varscan2
- ZFHX4 | c.565C>A p.P189T | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51500124; called by muse, mutect2, varscan2
- ZGRF1 | c.5741C>T p.T1914I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs763714033, COSV71393907; called by muse, mutect2, varscan2
- ZNF211 | c.287A>C p.Q96P (on ENST00000347302 / NM_198855.4; = p.Q109P on NM_006385.5) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); catalogued as COSV53746197; called by muse, mutect2, varscan2
- ZNF211 | c.1682G>T p.G561V (on ENST00000347302 / NM_198855.4; = p.G574V on NM_006385.5) | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV53746212, COSV99560086; called by muse, mutect2, varscan2
- ZNF217 | c.1838A>T p.K613I | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as COSV56603415; called by muse, mutect2, varscan2
- ZNF268 | c.800A>G p.Q267R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV57214618; called by muse, mutect2, varscan2
- ZNF43 | c.1117A>G p.T373A | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs1457608318, COSV61686323; called by muse, mutect2, varscan2
- ZNF473 | c.1303G>C p.E435Q | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV54525424; called by muse, mutect2, varscan2
- ZNF473 | c.1675G>C p.E559Q | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV54525434; called by muse, mutect2, varscan2
- ZNF527 | c.1511G>A p.G504E | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as COSV62236276; called by muse, mutect2, varscan2
- ZNF595 | c.901G>C p.E301Q | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.05); catalogued as COSV100227856, COSV59554339; called by muse, mutect2, varscan2
- CCDC198 | c.373dup p.R125Kfs*22 | Frame Shift Ins (INS) | VAF 14/34 reads (41%) | called by mutect2, varscan2
- CCDC198 | c.372delinsAA p.R125Kfs*22 | Frame Shift Ins (INS) | VAF 19/51 reads (37%) | called by mutect2*, pindel, varscan2*
- DSG3 | c.1042del p.A348Lfs*27 | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | called by mutect2, pindel, varscan2
- FRY | c.8722del p.M2908Cfs*5 | Frame Shift Del (DEL) | VAF 17/57 reads (30%) | called by mutect2, pindel, varscan2
- HIVEP3 | c.3328_3339del p.P1110_P1113del | In Frame Del (DEL) | VAF 16/63 reads (25%) | called by mutect2, pindel, varscan2
- IGHV1OR21-1 | c.23T>A p.L8Q | Missense Mutation (SNP) | VAF 30/376 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- PASK | c.932dup p.S312Efs*17 | Frame Shift Ins (INS) | VAF 9/47 reads (19%) | called by mutect2, pindel, varscan2
- TM6SF2 | c.412_413delinsA p.N139Ifs*12 | Frame Shift Del (DEL) | VAF 16/122 reads (13%) | called by pindel, varscan2*
- TRGV2 | c.82T>A p.S28T | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.397); called by muse, varscan2
- WDR1 | c.897del p.Y300Tfs*27 (on ENST00000382452; = p.Y160Tfs*27 on NM_005112.5) | Frame Shift Del (DEL) | VAF 7/17 reads (41%) | called by mutect2, varscan2
- ZBTB11 | c.981_983dup p.A328dup | In Frame Ins (INS) | VAF 13/69 reads (19%) | called by mutect2, pindel, varscan2
- ABCC8 | c.1599C>G p.L533= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV100217651, COSV56858728; called by muse, mutect2, varscan2
- ABLIM3 | c.294C>A p.G98= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV58649551; called by muse, mutect2
- ACACB | c.3945G>T p.P1315= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV58148468; called by muse, mutect2, varscan2
- ADAM29 | c.552T>A p.T184= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV63668940; called by muse, mutect2, varscan2
- AHNAK2 | c.5802C>T p.D1934= | Silent (SNP) | VAF 147/310 reads (47%) | catalogued as rs374219885; called by muse, mutect2, varscan2
- ALOX5 | c.315C>A p.T105= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV65554911; called by muse, mutect2, varscan2
- ANO5 | c.583C>A p.R195= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as COSV61088148, COSV61090944; called by muse, mutect2, varscan2
- APOB | c.2361C>T p.A787= | Silent (SNP) | VAF 25/90 reads (28%) | catalogued as rs1446090393, COSV51955819; called by muse, mutect2, varscan2
- AQP6 | c.177C>T p.A59= | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as rs373926524; called by muse, mutect2, varscan2
- ARHGEF40 | c.2331G>T p.V777= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV53884897; called by muse, mutect2, varscan2
- ARPP21 | c.1242C>T p.S414= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs932106872, COSV51809802; called by muse, mutect2, varscan2
- ATP13A4 | c.3024A>T p.T1008= | Silent (SNP) | VAF 64/256 reads (25%) | catalogued as COSV61328536; called by muse, mutect2, varscan2
- B3GNT2 | c.277C>T p.L93= | Silent (SNP) | VAF 174/416 reads (42%) | catalogued as rs761889404, COSV57345382; called by muse, mutect2, varscan2
- BBOX1 | c.1044C>T p.G348= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV54194812; called by muse, mutect2, varscan2
- CADPS2 | c.1950C>T p.L650= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as COSV57389049; called by muse, mutect2, varscan2
- CARD6 | c.1284G>T p.V428= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV54569695; called by muse, mutect2, varscan2
- CCDC40 | c.2094G>A p.L698= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100884254, COSV66479175; called by muse, mutect2, varscan2
- CCDC89 | c.165G>T p.L55= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV57035047; called by muse, mutect2, varscan2
- CDH12 | c.1530C>A p.V510= | Silent (SNP) | VAF 30/150 reads (20%) | catalogued as COSV66454245; called by muse, mutect2, varscan2
- CDH12 | c.138G>T p.R46= | Silent (SNP) | VAF 39/204 reads (19%) | catalogued as COSV66454253; called by muse, mutect2, varscan2
- CLVS1 | c.279C>A p.L93= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as rs754367710, COSV57984447; called by muse, mutect2, varscan2
- CNTLN | c.2745A>G p.Q915= | Silent (SNP) | VAF 48/142 reads (34%) | catalogued as rs1282033215, COSV52100252; called by muse, mutect2, varscan2
- COL14A1 | c.2487C>A p.S829= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV52870840; called by muse, mutect2, varscan2
- COL1A2 | c.534C>A p.G178= | Silent (SNP) | VAF 28/133 reads (21%) | catalogued as COSV51967339; called by muse, mutect2, varscan2
- CPN2 | c.852C>T p.L284= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as rs754431425, COSV60472302; called by mutect2, varscan2
- CRYBG1 | c.4368T>A p.S1456= | Silent (SNP) | VAF 35/109 reads (32%) | catalogued as COSV64815005; called by muse, mutect2, varscan2
- DBNL | c.1062T>C p.G354= (on ENST00000448521 / NM_001014436.3; = p.G355= on NM_014063.7) | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV51979913; called by muse, mutect2
- DCC | c.1164T>A p.L388= | Silent (SNP) | VAF 27/145 reads (19%) | catalogued as COSV59141266; called by muse, mutect2, varscan2
- DDIT3 | c.387G>A p.R129= | Silent (SNP) | VAF 30/132 reads (23%) | catalogued as COSV56257451, COSV56259196; called by muse, mutect2, varscan2
- DGKK | c.1518C>A p.I506= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as COSV65707077, COSV65709601; called by muse, mutect2, varscan2
- DOCK4 | c.2842C>T p.L948= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV70244117; called by muse, mutect2, varscan2
- FKTN | c.444C>T p.D148= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as rs759808323, COSV56312629; ClinVar: likely benign; called by muse, mutect2, varscan2
- FUT9 | c.769C>T p.L257= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV56142295, COSV56158434; called by muse, mutect2, varscan2
- GAPDHS | c.822C>A p.A274= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV55881547, COSV55881555; called by muse, mutect2, varscan2
- GPR176 | c.798C>T p.A266= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV54449026; called by muse, mutect2, varscan2
- GPR18 | c.474G>C p.L158= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV61621545; called by muse, mutect2, varscan2
- GRIA2 | c.312C>T p.C104= | Silent (SNP) | VAF 26/127 reads (20%) | catalogued as rs767578632, COSV52408659; called by muse, mutect2, varscan2
- IFNL2 | c.528C>T p.A176= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs1568559367, COSV59594330; called by muse, mutect2, varscan2
- INTS10 | c.1191A>T p.V397= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV67605191; called by muse, mutect2
- ITGB2 | c.1617G>T p.G539= (on ENST00000302347; = p.G515= on NM_000211.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV56614708; called by muse, mutect2, varscan2
- KIF5A | c.1674G>T p.L558= | Silent (SNP) | VAF 32/119 reads (27%) | catalogued as COSV54059843; called by muse, mutect2, varscan2
- KIFC2 | c.351G>T p.L117= | Silent (SNP) | VAF 47/97 reads (48%) | catalogued as COSV56761264, COSV56763235; called by muse, mutect2, varscan2
- KRTAP13-2 | c.249C>T p.P83= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV67762147, COSV67762369; called by muse, mutect2, varscan2
- LARP4B | c.1560A>G p.P520= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV60224400; called by muse, mutect2, varscan2
- LVRN | c.1530C>A p.A510= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV63498630; called by muse, mutect2, varscan2
- MAPKBP1 | c.1047C>T p.A349= (on ENST00000456763 / NM_001128608.2; = p.A343= on NM_014994.3) | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as rs1567150100, COSV52967715; called by muse, mutect2, varscan2
- MCM10 | c.549A>G p.L183= (on ENST00000484800 / NM_182751.3; = p.L182= on NM_018518.5) | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs1162318076, COSV66337169; called by muse, mutect2, varscan2
- MPEG1 | c.711C>A p.T237= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV57093211, COSV99915197; called by mutect2, varscan2
- MYH15 | c.3562C>A p.R1188= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV99842780; called by muse, mutect2, varscan2
- MYH6 | c.663C>T p.I221= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as COSV62454906; called by muse, mutect2, varscan2
- MYO7B | c.1731C>A p.I577= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs768009458, COSV67347944, COSV67352665; called by muse, mutect2, varscan2
- NLRP4 | c.1083G>T p.L361= | Silent (SNP) | VAF 31/63 reads (49%) | catalogued as COSV56724764; called by muse, mutect2, varscan2
- OR10A7 | c.147C>A p.T49= | Silent (SNP) | VAF 62/239 reads (26%) | catalogued as COSV58279669; called by muse, mutect2, varscan2
- OR1S1 | c.283C>T p.L95= | Silent (SNP) | VAF 21/149 reads (14%) | catalogued as rs762263275, COSV58708977; called by muse, mutect2, varscan2
- OR2T27 | c.726C>T p.S242= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1336369390, COSV61283868; called by muse, mutect2, varscan2
- OR4K14 | c.192G>T p.L64= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV59294490; called by muse, mutect2, varscan2
- OR5D18 | c.696C>G p.V232= | Silent (SNP) | VAF 28/100 reads (28%) | catalogued as COSV61737108, COSV61738898; called by muse, mutect2, varscan2
- OR5T2 | c.138T>C p.T46= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV57591437; called by muse, mutect2, varscan2
- PCDH17 | c.2217T>A p.T739= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV64980285; called by muse, mutect2, varscan2
- PCDH9 | c.2838T>A p.P946= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as COSV60595955; called by muse, mutect2, varscan2
- PCDHA2 | c.2128C>T p.L710= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as COSV65371684; called by muse, mutect2, varscan2
- PCDHA3 | c.1671C>T p.D557= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as rs199682432, COSV63539775; called by muse, mutect2, varscan2
- PCNX4 | c.2853A>G p.E951= (on ENST00000406854 / NM_001330177.2; = p.E717= on NM_022495.5) | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV58308788; called by muse, mutect2, varscan2
- PDCL3 | c.168G>T p.L56= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as COSV51810484; called by muse, mutect2, varscan2
- PLCB1 | c.3540T>C p.G1180= | Silent (SNP) | VAF 59/273 reads (22%) | catalogued as COSV62071272; called by muse, mutect2, varscan2
- PLEKHA5 | c.1899A>G p.V633= | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as rs146976787; called by muse, mutect2, varscan2
- PPP1R13L | c.2166C>T p.T722= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV62909951; called by mutect2, varscan2
- PPP4R3B | c.2352T>C p.N784= (on ENST00000616407 / NM_001122964.3; = p.N699= on NM_020463.4) | Silent (SNP) | VAF 9/222 reads (4%) | catalogued as COSV55409806; called by muse, mutect2
- PRKDC | c.8307C>G p.V2769= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as COSV100042299, COSV58066106; called by muse, mutect2, varscan2
- SART3 | c.2208G>A p.P736= (on ENST00000228284; = p.P718= on NM_014706.4) | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs764331130, COSV57210986; called by muse, mutect2, varscan2
- SEMG1 | c.237C>T p.S79= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as rs1461279518, COSV54874891, COSV99725573; called by muse, mutect2, varscan2
- SHANK1 | c.1878G>A p.K626= | Silent (SNP) | VAF 23/129 reads (18%) | catalogued as COSV53264034; called by muse, mutect2, varscan2
- SHOX2 | c.351C>T p.S117= (on ENST00000441443 / NM_006884.3; = p.S141= on NM_003030.4) | Silent (SNP) | VAF 16/111 reads (14%) | catalogued as COSV67464875; called by muse, mutect2, varscan2
- SLC4A2 | c.3525C>T p.A1175= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV52542584; called by muse, mutect2, varscan2
- SORT1 | c.432A>T p.L144= | Silent (SNP) | VAF 33/146 reads (23%) | catalogued as COSV56671069; called by muse, mutect2, varscan2
- STAB2 | c.3387A>T p.P1129= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV66348267; called by muse, mutect2, varscan2
- SUSD5 | c.849A>G p.S283= | Silent (SNP) | VAF 28/53 reads (53%) | catalogued as COSV58881108; called by muse, mutect2, varscan2
- TBX2 | c.774C>A p.T258= | Silent (SNP) | VAF 46/69 reads (67%) | catalogued as COSV53601486, COSV99538584; called by muse, mutect2, varscan2
- TGFBR2 | c.726G>A p.L242= | Silent (SNP) | VAF 30/50 reads (60%) | catalogued as COSV55461948; called by muse, mutect2, varscan2
- THADA | c.5085T>C p.P1695= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as COSV57694528; called by muse, mutect2, varscan2
- THSD4 | c.2136G>A p.L712= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV55986874; called by muse, mutect2, varscan2
- TPRG1 | c.405G>T p.L135= | Silent (SNP) | VAF 37/149 reads (25%) | catalogued as rs368818406, COSV61469330; called by muse, mutect2, varscan2
- TPTE2 | c.654C>T p.D218= (on ENST00000400230 / NM_199254.2; = p.D141= on NM_130785.3) | Silent (SNP) | VAF 33/160 reads (21%) | catalogued as COSV55016700; called by muse, mutect2, varscan2
- TTN | c.80121T>A p.V26707= (on ENST00000591111; = p.V19283= on NM_003319.4) | Silent (SNP) | VAF 42/150 reads (28%) | catalogued as COSV60391705; called by muse, mutect2, varscan2
- TTN | c.68262T>C p.Y22754= (on ENST00000591111; = p.Y15330= on NM_003319.4) | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV60391726; called by muse, mutect2, varscan2
- TTN | c.20304C>A p.V6768= (on ENST00000591111; = p.V5841= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV60391873; called by muse, mutect2, varscan2
- VPS13D | c.9360G>A p.V3120= | Silent (SNP) | VAF 33/114 reads (29%) | catalogued as COSV50699453; called by muse, mutect2, varscan2
- VWA3B | c.2058G>A p.Q686= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV68247324; called by muse, mutect2, varscan2
- XIRP2 | c.7572C>A p.P2524= (on ENST00000628543; = p.P2699= on NM_152381.6) | Silent (SNP) | VAF 30/123 reads (24%) | catalogued as COSV99740735; called by muse, mutect2, varscan2
- ZNF106 | c.1971A>G p.T657= | Silent (SNP) | VAF 40/131 reads (31%) | catalogued as COSV55522584; called by muse, mutect2, varscan2
- ZNF169 | c.774G>T p.G258= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV61766941; called by muse, mutect2, varscan2
- ZNF518A | c.1974A>G p.A658= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as rs369974270; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849192 G>C | 5'Flank (SNP) | VAF 16/27 reads (59%) | called by muse, mutect2, varscan2
- ASCC3 | c.241+4883A>C | Intron (SNP) | VAF 17/67 reads (25%) | catalogued as rs1024629998, COSV100225478; called by muse, mutect2, varscan2
- BCL11A | chr2:60452621 T>G | 3'Flank (SNP) | VAF 11/186 reads (6%) | catalogued as COSV59638479; called by muse, mutect2
- EGFL7 | c.571+280A>T | Intron (SNP) | VAF 17/25 reads (68%) | catalogued as COSV58248957; called by muse, mutect2, varscan2
- OR2T33 | c.*2C>A | 3'UTR (SNP) | VAF 24/110 reads (22%) | catalogued as COSV100531747; called by muse, mutect2, varscan2
- PREP | c.-48G>C | 5'UTR (SNP) | VAF 18/59 reads (31%) | catalogued as rs774243006, COSV64872553; called by muse, mutect2, varscan2
- SNORD116-25 | n.30A>T | RNA (SNP) | VAF 19/76 reads (25%) | called by muse, mutect2, varscan2
- SSPOP | n.2911G>C | RNA (SNP) | VAF 13/47 reads (28%) | catalogued as COSV50489586; called by muse, mutect2, varscan2
- UCHL5 | c.-159G>T | 5'UTR (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100814601; called by muse, mutect2, varscan2
- XIRP2 | c.*6G>A | 3'UTR (SNP) | VAF 11/33 reads (33%) | catalogued as COSV99736854; called by muse, mutect2, varscan2
